Somatic mutation profile of tumor specimen 0DPCXY from CCDI case PBCDLX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.6 years (3,152 days).
Specimen 0DPCXY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73188605-fe26-4758-bfc6-15e263aca8a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPCXS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a52fd21e-29a2-4351-ab8a-bc3c68c974d4

The open-access MAF lists 41 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 5, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP26 | c.1837+1G>A p.X613_splice | Splice Site (SNP) | VAF 300/643 reads (47%) | catalogued as rs1427468777, COSV50832069; called by muse, varscan2
- CTDNEP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 322/395 reads (82%) | catalogued as COSV56642845; called by muse, varscan2
- DDR2 | c.1943A>T p.D648V | Missense Mutation (SNP) | VAF 417/913 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63373336; called by muse, varscan2
- FBN2 | c.2711A>G p.D904G | Missense Mutation (SNP) | VAF 351/864 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV52524277; called by muse, varscan2
- KRT6B | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 464/1230 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs773449867; called by muse, varscan2
- MKLN1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 150/542 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1472028873, COSV61759880; called by muse, varscan2
- PCDH17 | c.3148A>C p.T1050P | Missense Mutation (SNP) | VAF 354/728 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.188); catalogued as COSV64977351; called by muse, varscan2
- SALL3 | c.2661G>C p.E887D | Missense Mutation (SNP) | VAF 250/518 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV73306351; called by muse, varscan2
- SART3 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 296/690 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1324092908; called by muse, varscan2
- TARS3 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 150/340 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV60107963; called by muse, varscan2
- ZNF93 | c.295A>T p.I99L | Missense Mutation (SNP) | VAF 272/631 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as rs750766392; called by muse, varscan2
- AP3B2 | c.3019C>G p.L1007V (on ENST00000261722; = p.L1001V on NM_004644.5) | Missense Mutation (SNP) | VAF 276/622 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.321); called by muse, varscan2
- C10orf71 | c.3466A>T p.R1156* | Nonsense Mutation (SNP) | VAF 227/500 reads (45%) | called by muse, varscan2
- CFAP70 | c.3145C>T p.L1049F | Missense Mutation (SNP) | VAF 126/298 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, varscan2
- COL18A1 | c.4420_4422del p.E1474del (on ENST00000359759 / NM_130444.3; = p.E1239del on NM_030582.4) | In Frame Del (DEL) | VAF 400/990 reads (40%) | called by pindel, varscan2
- DLGAP1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 245/506 reads (48%) | called by muse, varscan2
- HERC2 | c.5983G>A p.G1995R | Missense Mutation (SNP) | VAF 344/778 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- PSG2 | c.169A>C p.N57H | Missense Mutation (SNP) | VAF 440/1059 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- RGS13 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 222/510 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RRM1 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 264/564 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STRAP | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, varscan2
- TAS1R2 | c.2155T>C p.S719P | Missense Mutation (SNP) | VAF 380/795 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- TASOR2 | c.1037G>C p.R346T | Missense Mutation (SNP) | VAF 594/1269 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- ZBTB16 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 226/512 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.03); called by muse, varscan2
- DACT1 | c.1911G>A p.G637= | Silent (SNP) | VAF 334/772 reads (43%) | called by muse, varscan2
- GABRA2 | c.315A>G p.K105= | Silent (SNP) | VAF 198/433 reads (46%) | called by muse, varscan2
- NBPF9 | c.771T>C p.I257= | Silent (SNP) | VAF 40/338 reads (12%) | catalogued as rs1553654638; called by muse, varscan2
- NEMP2 | c.981A>G p.K327= | Silent (SNP) | VAF 238/502 reads (47%) | called by muse, varscan2
- NPFFR1 | c.1164C>T p.G388= | Silent (SNP) | VAF 302/602 reads (50%) | called by muse, varscan2
- RYR2 | c.7302C>T p.G2434= | Silent (SNP) | VAF 224/750 reads (30%) | catalogued as rs766592875, COSV63698995; ClinVar: likely benign; called by muse, varscan2
- TBC1D9B | c.975C>T p.I325= | Silent (SNP) | VAF 457/1005 reads (45%) | called by muse, varscan2
- TRERF1 | c.1818C>T p.T606= | Silent (SNP) | VAF 402/848 reads (47%) | catalogued as rs368567278; called by muse, varscan2
- AQP6 | c.*93C>A | 3'UTR (SNP) | VAF 74/151 reads (49%) | called by muse, varscan2
- C7orf25 | c.-74G>T | 5'UTR (SNP) | VAF 382/1100 reads (35%) | called by muse, varscan2
- CACTIN | c.1786+24G>T | Intron (SNP) | VAF 104/258 reads (40%) | called by muse, varscan2
- DTX4 | c.1375-39C>G | Intron (SNP) | VAF 240/412 reads (58%) | called by muse, varscan2
- HM13 | c.724+14C>G | Intron (SNP) | VAF 272/586 reads (46%) | called by muse, varscan2
- INSRR | c.3397+12G>T | Intron (SNP) | VAF 294/747 reads (39%) | called by muse, varscan2
- KRT37 | c.-30G>T | 5'UTR (SNP) | VAF 144/290 reads (50%) | called by muse, varscan2
- MAMDC2 | c.1499-52C>A | Intron (SNP) | VAF 89/188 reads (47%) | called by muse, varscan2
- SCD5 | c.*57T>C | 3'UTR (SNP) | VAF 188/391 reads (48%) | called by muse, varscan2
